TARGET case TARGET-10-PALNTB — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e818e557-99de-5b01-8d9c-3f913a150ac0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Dead; Days to death: 1,415 days (3.9 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 8.7 years (3,179 days); Year of diagnosis: 2002; Days to last follow up: 1,415 days (3.9 years).
   Treatment given: Protocol identifier: P9906.

Follow-up (3 entries)
- Days to follow up: 1,023 days (2.8 years); Days to first event: 1,023 days (2.8 years); First event: Relapse.
- Days to follow up: 1,415 days (3.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Year of follow up: 2006.
- Days to follow up: 1,415 days (3.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 315 ×10³/µL.
- Day 8: Minimal Residual Disease (Flow Cytometry) 3.19%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (19 samples)
- Sample TARGET-10-PALNTB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-10-PALNTB-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PALNTB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PALNTB-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-PALNTB-60.10A, TARGET-10-PALNTB-60.11A, TARGET-10-PALNTB-60.12A, TARGET-10-PALNTB-60.1A, TARGET-10-PALNTB-60.1B, TARGET-10-PALNTB-60.2A, TARGET-10-PALNTB-60.3A, TARGET-10-PALNTB-60.4A, TARGET-10-PALNTB-60.4B, TARGET-10-PALNTB-60.5A, TARGET-10-PALNTB-60.5B, TARGET-10-PALNTB-60.6B, TARGET-10-PALNTB-60.7A, TARGET-10-PALNTB-60.8A, TARGET-10-PALNTB-60.9A (15 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 1415
- WBC at Diagnosis: 314.8
- CNS Status at Diagnosis: CNS 2
- MRD Day 8: 3.19
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.1
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 29: 2
- Karyotype: 47,XX,+X[20]/46,XX[6]
- DNA Index: 1
- Alternate Therapy: Chemotherapy
- Cell of Origin: B precursor (Non-T, Non-B ALL)
- ALL Molecular Subtype: None of above

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Protocol: 9906
- Cell of Origin: B Cell ALL
